Somatic mutation profile of tumor specimen MMRF_1815_1_BM_CD138pos (aliquot MMRF_1815_1_BM_CD138pos_T1_KBS5U_K11317) from MMRF case MMRF_1815, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.7 years (29,837 days).
Specimen MMRF_1815_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 846e2461-8ad3-4d22-b9f2-fe77e70e18bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1815_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1815_1_PB_CD3pos_C2_KBS5U_L07220; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7779c8a3-66de-49de-b183-949964afedbf

The open-access MAF lists 100 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 24, Intron 13, Silent 10, 5'UTR 4, RNA 3, 3'Flank 2, 5'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV52928378; called by muse, mutect2, varscan2
- APLP1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs368817415; called by muse, mutect2, varscan2
- ASTN1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs370485432; called by muse, mutect2, varscan2
- ATF7IP | c.2158+2T>C p.X720_splice | Splice Site (SNP) | VAF 59/100 reads (59%) | catalogued as COSV53770069; called by muse, mutect2, varscan2
- AURKAIP1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs369452592; called by muse, mutect2, varscan2
- CLEC4G | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.894); catalogued as rs1412695287, COSV61002980; called by muse, mutect2, varscan2
- CRAMP1 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99246161; called by muse, mutect2, varscan2
- FTMT | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs754484196, COSV100360367; called by muse, mutect2, varscan2
- LRRK2 | c.4750C>A p.H1584N | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100109853; called by muse, mutect2, varscan2
- NOC2L | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142878344; called by muse, mutect2, varscan2
- RCC1L | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 83/155 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1187558913; called by muse, mutect2, varscan2
- SCART1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs773400899; called by muse, mutect2, varscan2
- SNRNP200 | c.4886G>A p.R1629Q | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs780482691; called by muse, mutect2, varscan2
- XIRP2 | c.645G>T p.Q215H (on ENST00000628543; = p.Q390H on NM_152381.6) | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV54685729; called by muse, mutect2
- AGPS | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- BTBD2 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CDC42BPA | c.1579T>C p.F527L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP128 | c.3275A>T p.Y1092F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CHD1 | c.4286A>G p.K1429R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CMYA5 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CYP4V2 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELMOD1 | c.288A>T p.P96= | Splice Region (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- EVC | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FGFR3 | c.861G>T p.W287C | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GML | c.407C>G p.T136S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HCN4 | c.3016C>G p.L1006V | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB6B | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDHA2 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PHF12 | c.1706A>T p.N569I | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- REV1 | c.2749C>T p.H917Y | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RICTOR | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SCAF8 | c.3401G>A p.S1134N | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCN11A | c.2299G>C p.G767R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIRT2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A9 | c.1178T>G p.L393W | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC27A3 | c.2363A>G p.Q788R (on ENST00000271857; = p.Q660R on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SMARCA5 | c.1781A>G p.H594R | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPON2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TSHZ3 | c.3119C>A p.S1040Y | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TTC32 | c.357A>C p.L119F | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- XIRP1 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF248 | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ZNF569 | c.1171T>G p.F391V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- APC2 | c.2655G>A p.R885= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as rs758239892; called by muse, mutect2, varscan2
- EGF | c.930T>C p.T310= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1440454679; called by muse, mutect2
- IGHD3-9 | c.3A>G p.V1= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as rs140560472; called by muse, varscan2
- IGLV3-1 | c.99A>C p.P33= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs373803208; called by muse, varscan2
- OTOL1 | c.1128C>T p.V376= | Silent (SNP) | VAF 48/168 reads (29%) | called by muse, mutect2, varscan2
- PKD1L3 | c.4275C>T p.H1425= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs780037590; called by muse, mutect2, varscan2
- PPP1R13L | c.2355C>T p.V785= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV62908343; called by muse, mutect2, varscan2
- PRKCG | c.717G>T p.R239= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as rs1418483481; called by muse, mutect2, varscan2
- PTH2R | c.1179C>T p.I393= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV55915363; called by muse, mutect2, varscan2
- TECTA | c.4416G>A p.L1472= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- ABHD5 | c.-23C>T | 5'UTR (SNP) | VAF 30/52 reads (58%) | catalogued as rs779262076, COSV99185468; called by mutect2, varscan2
- ADD2 | c.1742-276G>T | Intron (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100035519; called by muse, mutect2, varscan2
- ASAH1 | c.126+747G>A | Intron (SNP) | VAF 55/55 reads (100%) | called by muse, mutect2, varscan2
- CEP41 | c.*1396A>T | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- CRACD | c.*372T>C | 3'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- CRB2 | c.*887G>A | 3'UTR (SNP) | VAF 101/220 reads (46%) | called by muse, mutect2, varscan2
- DNAJC6 | c.*797G>A | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- EAPP | c.74+98G>A | Intron (SNP) | VAF 97/201 reads (48%) | called by muse, mutect2, varscan2
- EIF4A2 | c.-14T>A | 5'UTR (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- EIF5A2 | c.*3240A>G | 3'UTR (SNP) | VAF 33/124 reads (27%) | catalogued as rs1474298574; called by muse, mutect2, varscan2
- ENOSF1 | chr18:673369 T>A | 3'Flank (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- FYCO1 | c.*1478T>C | 3'UTR (SNP) | VAF 66/130 reads (51%) | called by muse, mutect2, varscan2
- HLA-DOA | c.614-34T>A | Intron (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- HOXA7 | c.*1001C>T | 3'UTR (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- INSL5 | c.*162G>C | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- KRAS | c.*2670T>C | 3'UTR (SNP) | VAF 16/24 reads (67%) | called by mutect2, varscan2
- LAMTOR5 | c.-3G>A | 5'UTR (SNP) | VAF 92/192 reads (48%) | catalogued as COSV99862135; called by muse, mutect2, varscan2
- LINC00482 | n.666G>T | RNA (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- MMS22L | c.*997C>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- MRPL49 | c.*808T>C | 3'UTR (SNP) | VAF 11/105 reads (10%) | catalogued as rs1178338978; called by muse, mutect2, varscan2
- MTHFD2L | c.*969A>G | 3'UTR (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- MYOC | c.*322G>A | 3'UTR (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- NCK2 | c.*401G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs866255790; called by muse, mutect2
- PCDH9 | c.3036+635C>G | Intron (SNP) | VAF 17/17 reads (100%) | catalogued as rs1453346976; called by muse, mutect2, varscan2
- PPATP1 | n.953G>A | RNA (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- RAB3B | c.*8008T>A | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- RHEBL1 | c.-145T>A | 5'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- RN7SL211P | chr2:64904416 G>A | 3'Flank (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
- RNF125 | c.*1438C>G | 3'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, varscan2
- RRM2 | n.1575G>C | RNA (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- SARS2 | c.393+112A>G | Intron (SNP) | VAF 30/225 reads (13%) | catalogued as rs765930179, COSV55499796; called by muse, mutect2, varscan2
- SIKE1 | c.159+29C>G | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- SLC3A1 | c.766-340C>A | Intron (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44095T>A | Intron (SNP) | VAF 96/206 reads (47%) | called by muse, mutect2, varscan2
- SNX10 | c.*1498G>A | 3'UTR (SNP) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- SNX30 | c.*1251G>T | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- SOCS6 | c.*2983G>C | 3'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs758699116; called by muse, mutect2, varscan2
- SP3 | c.*1238A>C | 3'UTR (SNP) | VAF 9/18 reads (50%) | catalogued as rs1238212950; called by muse, mutect2, varscan2
- SPA17 | c.*1368G>T | 3'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- SPAG8 | c.1201-32G>A | Intron (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- SRGAP3 | c.*1786T>C | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- SYBU | c.531-454C>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- TP53TG5 | c.*77A>G | 3'UTR (SNP) | VAF 56/243 reads (23%) | catalogued as rs944889221; called by muse, mutect2, varscan2
- TTN | c.62714-67G>C | Intron (SNP) | VAF 20/28 reads (71%) | catalogued as COSV100600446; called by muse, mutect2, varscan2
- UNC5C | chr4:95549156 G>A | 5'Flank (SNP) | VAF 3/54 reads (6%) | called by muse, mutect2
- ZFP90 | c.161-90A>C | Intron (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- ZNF569 | c.*505T>A | 3'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
